Somatic mutation profile of tumor specimen MMRF_1790_2_BM_CD138pos (aliquot MMRF_1790_2_BM_CD138pos_T1_KHS5U_L11096) from MMRF case MMRF_1790, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 76.8 years (28,045 days).
Specimen MMRF_1790_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b170381f-6557-4eab-9003-25876b571619.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1790_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1790_1_PB_WBC_C3_KBS5U_L07232; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9cb6ac0-dad1-4c4d-bdf4-532683c44742

The open-access MAF lists 94 somatic variants for this specimen: 39 protein-altering or splice-affecting, 12 silent, 43 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, 3'UTR 26, Silent 12, 3'Flank 5, Intron 4, 5'UTR 4, RNA 2, 5'Flank 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYC | c.173C>T p.T58I (on ENST00000377970; = p.T73I on NM_002467.6) | Missense Mutation (SNP) | VAF 33/191 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756091827, COSV52367994, COSV52373588; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACTL7B | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as rs139165156; called by muse, mutect2, varscan2
- ADAT3 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 26/181 reads (14%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs758520906; called by muse, mutect2, varscan2
- ASXL3 | c.6347C>T p.A2116V | Missense Mutation (SNP) | VAF 15/193 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.59); catalogued as rs757112357, COSV52466903, COSV52470266; called by muse, mutect2
- DNAI3 | c.446T>G p.V149G | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as rs1409802552; called by muse, mutect2, varscan2
- DPP6 | c.692G>A p.S231N (on ENST00000377770 / NM_001364500.2; = p.S169N on NM_001936.5) | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs538699484; called by muse, mutect2
- EGF | c.2594G>A p.G865E | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768471434; called by muse, mutect2, varscan2
- FRAS1 | c.4951C>T p.R1651* | Nonsense Mutation (SNP) | VAF 15/44 reads (34%) | catalogued as rs753960106, COSV99347169, COSV99347494; called by muse, mutect2, varscan2
- IRF4 | c.296G>C p.C99S | Missense Mutation (SNP) | VAF 63/170 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66705766; called by muse, mutect2, varscan2
- ITFG1 | c.613C>A p.H205N | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as COSV100278612; called by muse, mutect2
- KCNB1 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1338339252, COSV65568401; called by muse, mutect2, varscan2
- KRT37 | c.977C>T p.T326M | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs140701476, COSV56659104; called by muse, mutect2, varscan2
- LINGO2 | c.214G>A p.V72I | Missense Mutation (SNP) | VAF 88/253 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as rs781520934, COSV58057149; called by muse, mutect2, varscan2
- PCDHA4 | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.12); catalogued as COSV63543187; called by muse, mutect2
- PRRT4 | c.2389G>A p.A797T | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs867388733; called by muse, mutect2, varscan2
- TMED10 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 34/179 reads (19%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs771551323; called by muse, mutect2, varscan2
- UNC80 | c.5173C>T p.R1725C | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1201504693; called by muse, mutect2, varscan2
- AL645922.1 | c.109C>T p.L37F | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANKRD35 | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDK8 | c.457A>G p.K153E | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- DAAM1 | c.3180T>G p.I1060M | Missense Mutation (SNP) | VAF 24/296 reads (8%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.76); called by muse, mutect2
- DNAH10 | c.1114G>C p.E372Q (on ENST00000409039; = p.E311Q on NM_207437.3) | Missense Mutation (SNP) | VAF 78/222 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- IFNAR1 | c.593A>T p.Y198F | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGF2BP3 | c.619G>C p.V207L | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IGHD1-7 | c.5T>G p.I2R | Missense Mutation (SNP) | VAF 15/20 reads (75%) | PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IGSF10 | c.1173C>A p.S391R | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.269); called by muse, mutect2
- KCNN2 | c.1105T>G p.Y369D (on ENST00000264773; = p.Y581D on NM_021614.4) | Missense Mutation (SNP) | VAF 104/260 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- MALRD1 | c.200G>T p.C67F | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); called by mutect2, varscan2
- MXRA5 | c.527T>G p.F176C | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- OSBPL3 | c.1363C>T p.Q455* | Nonsense Mutation (SNP) | VAF 11/248 reads (4%) | called by muse, mutect2
- PCDHAC2 | c.1531A>T p.R511W | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2
- PRKD2 | c.1151T>G p.V384G | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PTX4 | c.887C>T p.A296V (on ENST00000447419 / NM_001328608.2; = p.A291V on NM_001013658.1) | Missense Mutation (SNP) | VAF 64/176 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- RETREG1 | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, varscan2
- SLU7 | c.1396T>A p.S466T | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- SVEP1 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 10/205 reads (5%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.583); called by muse, mutect2
- TPTE | c.1586C>T p.S529L (on ENST00000618007 / NM_199261.4; = p.S511L on NM_199259.4) | Missense Mutation (SNP) | VAF 109/839 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- USP45 | c.1774G>T p.G592W | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); called by muse, mutect2
- VPS13D | c.11177G>C p.G3726A | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- AC099489.1 | c.3273G>T p.R1091= | Silent (SNP) | VAF 26/64 reads (41%) | called by muse, mutect2, varscan2
- ADCY7 | c.822G>A p.R274= | Silent (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- CLCN6 | c.1920C>T p.R640= | Silent (SNP) | VAF 46/110 reads (42%) | catalogued as rs142493749; called by muse, mutect2, varscan2
- FAM135A | c.4248T>C p.N1416= (on ENST00000370479 / NM_001351599.1; = p.N1203= on NM_020819.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- GTF3C1 | c.5808T>C p.S1936= | Silent (SNP) | VAF 90/264 reads (34%) | called by muse, varscan2
- MACF1 | c.10332A>G p.Q3444= | Silent (SNP) | VAF 59/167 reads (35%) | called by muse, mutect2, varscan2
- MAGEH1 | c.513G>C p.S171= | Silent (SNP) | VAF 40/261 reads (15%) | catalogued as rs1477245374; called by muse, mutect2, varscan2
- NOX5 | c.679C>T p.L227= | Silent (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2, varscan2
- NSMCE3 | c.222C>T p.A74= | Silent (SNP) | VAF 72/170 reads (42%) | called by muse, mutect2, varscan2
- SNTN | c.318C>A p.I106= | Silent (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- UBR4 | c.12219G>A p.K4073= | Silent (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
- UNC80 | c.2874C>T p.A958= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as rs756648889; called by muse, varscan2
- AEBP2 | c.*11C>T | 3'UTR (SNP) | VAF 45/378 reads (12%) | catalogued as rs187781821; called by muse, mutect2, varscan2
- AKAP5 | c.-897G>T | 5'UTR (SNP) | VAF 14/117 reads (12%) | called by muse, mutect2, varscan2
- AKAP5 | c.-806A>C | 5'UTR (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- AMACR | c.*2267C>T | 3'UTR (SNP) | VAF 7/90 reads (8%) | called by muse, mutect2
- APEX2 | c.*1237A>G | 3'UTR (SNP) | VAF 32/97 reads (33%) | called by muse, mutect2
- ARC | c.*450C>T | 3'UTR (SNP) | VAF 12/54 reads (22%) | catalogued as rs1007467632; called by muse, mutect2, varscan2
- ARMC10P1 | n.791C>G | RNA (SNP) | VAF 27/109 reads (25%) | called by muse, mutect2, varscan2
- ASTN1 | c.*2669G>A | 3'UTR (SNP) | VAF 12/64 reads (19%) | called by muse, mutect2, varscan2
- ATF4 | c.-92del | 5'UTR (DEL) | VAF 17/66 reads (26%) | called by pindel, varscan2
- BCL7A | chr12:122021118 C>T | 5'Flank (SNP) | VAF 70/186 reads (38%) | catalogued as COSV55851758; called by muse, mutect2, varscan2
- BMPR1B | chr4:95156198 T>C | 3'Flank (SNP) | VAF 8/144 reads (6%) | called by muse, mutect2
- CASK | chrX:41515648 G>C | 3'Flank (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
- CCNL1 | chr3:157160676 C>A | 5'Flank (SNP) | VAF 19/41 reads (46%) | called by muse, mutect2, varscan2
- CDH12 | c.*364A>T | 3'UTR (SNP) | VAF 20/57 reads (35%) | called by muse, mutect2, varscan2
- CYP2A7P2 | n.494C>T | RNA (SNP) | VAF 49/144 reads (34%) | called by muse, mutect2, varscan2
- ENTPD7 | c.*612A>G | 3'UTR (SNP) | VAF 10/122 reads (8%) | called by muse, mutect2
- ETV1 | chr7:13894071 ins G | 3'Flank (INS) | VAF 18/75 reads (24%) | called by mutect2, pindel, varscan2
- GPR158 | c.-193G>T | 5'UTR (SNP) | VAF 50/118 reads (42%) | catalogued as rs772745398; called by muse, mutect2, varscan2
- H2BC21 | c.*166G>A | 3'UTR (SNP) | VAF 8/87 reads (9%) | called by muse, mutect2, varscan2
- HS3ST1 | c.*1286G>A | 3'UTR (SNP) | VAF 32/75 reads (43%) | catalogued as rs1440186295; called by muse, mutect2, varscan2
- KRTAP19-5 | c.*143C>T | 3'UTR (SNP) | VAF 34/85 reads (40%) | called by muse, mutect2, varscan2
- NTRK2 | c.1397-56567G>A | Intron (SNP) | VAF 27/145 reads (19%) | catalogued as rs201221612, COSV52857899; called by muse, mutect2, varscan2
- PAX6 | chr11:31789695 T>G | 3'Flank (SNP) | VAF 11/270 reads (4%) | called by muse, mutect2
- PDE10A | c.*3942T>A | 3'UTR (SNP) | VAF 5/95 reads (5%) | called by muse, mutect2
- PLSCR4 | c.*1567A>T | 3'UTR (SNP) | VAF 16/138 reads (12%) | called by muse, mutect2, varscan2
- RAB40C | c.*128C>T | 3'UTR (SNP) | VAF 14/46 reads (30%) | called by muse, mutect2, varscan2
- RNF213 | c.10304-136G>T | Intron (SNP) | VAF 17/105 reads (16%) | called by muse, mutect2, varscan2
- RRAGD | c.*860A>C | 3'UTR (SNP) | VAF 17/110 reads (15%) | called by muse, mutect2, varscan2
- SEL1L | c.*2717_*2718insC | 3'UTR (INS) | VAF 14/71 reads (20%) | called by pindel, varscan2
- SEL1L | c.*2685T>G | 3'UTR (SNP) | VAF 28/88 reads (32%) | called by muse, varscan2
- SERP2 | c.158-6717T>C | Intron (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2
- SESTD1 | c.*4815A>G | 3'UTR (SNP) | VAF 81/232 reads (35%) | called by muse, mutect2, varscan2
- SH3RF3 | c.*2959G>A | 3'UTR (SNP) | VAF 15/50 reads (30%) | catalogued as rs1303542165; called by muse, mutect2, varscan2
- SHANK3 | c.2009-46C>T | Intron (SNP) | VAF 24/47 reads (51%) | catalogued as rs767314767; called by muse, mutect2, varscan2
- SIM1 | c.*537T>C | 3'UTR (SNP) | VAF 40/118 reads (34%) | called by muse, mutect2, varscan2
- SLC30A1 | c.*1825T>G | 3'UTR (SNP) | VAF 15/109 reads (14%) | called by muse, mutect2, varscan2
- SLITRK4 | chrX:143627492 ins C | 3'Flank (INS) | VAF 5/49 reads (10%) | called by mutect2*, varscan2
- STK16 | c.*912T>C | 3'UTR (SNP) | VAF 43/132 reads (33%) | called by muse, mutect2, varscan2
- TBX18 | c.*21A>G | 3'UTR (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100858428; called by mutect2, varscan2
- TDO2 | c.*258A>T | 3'UTR (SNP) | VAF 24/87 reads (28%) | called by muse, mutect2, varscan2
- THBS1 | c.*3781A>G | 3'UTR (SNP) | VAF 5/15 reads (33%) | called by muse, mutect2, varscan2
- ZBTB10 | c.*5217C>A | 3'UTR (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- ZFHX2 | c.*543C>T | 3'UTR (SNP) | VAF 6/124 reads (5%) | called by muse, mutect2
